Somatic mutation profile of tumor specimen TCGA-N8-A4PQ-01A (aliquot TCGA-N8-A4PQ-01A-11D-A28R-08) from TCGA case TCGA-N8-A4PQ, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Age at diagnosis: 76.0 years (27,772 days).
Specimen TCGA-N8-A4PQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba84d274-f3b9-4d8f-b6a3-338877c8bfe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PQ-10A (Blood Derived Normal), aliquot TCGA-N8-A4PQ-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f4fbc5c-0742-4253-ad25-b9c1cb8910ec

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Nonsense Mutation 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 24/32 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BTNL2 | c.1296C>A p.D432E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as COSV66630149; called by muse, mutect2, varscan2
- CD1D | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV63809567; called by muse, mutect2, varscan2
- CNTN3 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55176028; called by muse, mutect2, varscan2
- CNTN4 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs764462108; called by muse, mutect2, varscan2
- CRACD | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs773850855; called by muse, mutect2, varscan2
- DYSF | c.1916G>C p.R639P | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs150417363; called by muse, mutect2
- GRXCR1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs778774192, COSV67670223; called by muse, mutect2, varscan2
- KDELR2 | c.241A>C p.K81Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs769910193; called by muse, mutect2, varscan2
- MTR | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1241969409, COSV63965632; called by muse, mutect2, varscan2
- NCKAP1L | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs184942472; called by muse, mutect2, varscan2
- PROKR2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755743973, COSV54090060; called by muse, mutect2, varscan2
- PTCHD4 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs369189426; called by muse, mutect2, varscan2
- RHCG | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs149510924, COSV51516671; called by muse, mutect2, varscan2
- SAMD4B | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58750994; called by muse, mutect2, varscan2
- SGSH | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764585957, CM002403, COSV58340661; ClinVar: uncertain significance; called by muse, varscan2
- SSTR4 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.8); PolyPhen benign (0.017); catalogued as rs563434094, COSV54798866; called by muse, mutect2, varscan2
- STAB2 | c.7250C>T p.T2417M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs529403514, COSV66347247; called by muse, mutect2, varscan2
- TMPRSS9 | c.559C>T p.R187C (on ENST00000648592; = p.R153C on NM_182973.2) | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as rs141796619, COSV60232116; called by muse, mutect2, varscan2
- TRHR | c.1194T>A p.S398R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV61236058; called by muse, mutect2, varscan2
- ZNF384 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as rs1245479973; called by muse, mutect2, varscan2
- AKR1E2 | c.380A>T p.H127L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.036); called by muse, mutect2
- B4GALNT3 | c.2744C>G p.T915S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- BCL2L11 | c.486_498+2del p.X162_splice (on ENST00000393256 / NM_138621.5; = p.X102_splice on NM_006538.5) | Splice Site (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- CPA4 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HBA1 | c.423C>A p.Y141* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- HIVEP2 | c.4310G>A p.G1437D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF2B | c.1316T>G p.M439R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LNPEP | c.2705A>G p.D902G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- LRRC4B | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- MAG | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, varscan2
- MARCHF8 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MATR3 | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MEGF6 | c.2302G>T p.D768Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- MPHOSPH9 | c.873-1G>T p.X291_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- OR5D14 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PPFIA2 | c.3713A>T p.D1238V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); called by muse, mutect2
- PYY | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RDH14 | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SCN8A | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC43A1 | c.126C>G p.N42K | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, varscan2
- TEX2 | c.1653G>T p.M551I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TTLL6 | c.2185C>T p.Q729* (on ENST00000393382 / NM_001130918.3; = p.Q422* on NM_173623.3) | Nonsense Mutation (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- TTLL6 | c.2072C>T p.S691F (on ENST00000393382 / NM_001130918.3; = p.S384F on NM_173623.3) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.042); called by mutect2, varscan2
- UGDH | c.1106C>G p.P369R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP42 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, varscan2
- WDR72 | c.3008G>T p.S1003I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by mutect2, varscan2
- ZNF792 | c.1834C>G p.Q612E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYRIA | c.486C>A p.I162= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- FZD1 | c.1485C>G p.L495= | Silent (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2, varscan2
- GABRA1 | c.810C>G p.V270= | Silent (SNP) | VAF 62/72 reads (86%) | called by muse, mutect2, varscan2
- LARP4B | c.333C>T p.A111= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs747996928; called by muse, mutect2, varscan2
- LEXM | c.687C>A p.V229= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- NFATC2 | c.873G>A p.P291= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs751261116; called by muse, mutect2, varscan2
- OR10A6 | c.93C>T p.F31= | Silent (SNP) | VAF 90/116 reads (78%) | called by muse, mutect2, varscan2
- PHF24 | c.1191G>A p.K397= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1407393207; called by muse, mutect2, varscan2
- PPP2R2D | c.705C>A p.I235= | Silent (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- SHOX | c.502C>A p.R168= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as CM042777; called by muse, mutect2
- SS18L1 | c.240G>A p.T80= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs765950209, COSV100065096, COSV59213030; called by muse, mutect2, varscan2
- SYNE3 | c.1107C>T p.D369= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs772803780; called by muse, mutect2, varscan2
- WDR43 | c.1512G>A p.P504= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs761868010; called by muse, mutect2, varscan2
- ZKSCAN7 | c.927A>T p.A309= | Silent (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- PIGK | c.987-7282C>G | Intron (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
